Somatic mutation profile of tumor specimen BA2000D (aliquot aq-BA2000D) from BEATAML1.0 case 2304, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 24.5 years (8,964 days).
Specimen BA2000D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07437382-1cf5-4c29-9485-330e68b7e621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2533D (Solid Tissue Normal), aliquot aq-BA2533D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c0a24b5-ed57-4ac8-b7c7-6b839622ca47

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARNS1 | c.-8C>T | Splice Region (SNP) | VAF 18/54 reads (33%) | catalogued as rs927408061; called by muse, mutect2, varscan2
- GDF9 | c.1220A>G p.Y407C | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs764883262; called by muse, mutect2, varscan2
- LPA | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs771367882, COSV60310019; called by muse, mutect2, varscan2
- MAPT | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs766166210, COSV99290518; ClinVar: benign; called by muse, varscan2
- ZNF469 | c.6788C>T p.T2263I (on ENST00000437464; = p.T2291I on NM_001367624.2) | Missense Mutation (SNP) | VAF 119/243 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs992962962; called by muse, mutect2, varscan2
- BCL6 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CDON | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEBPA | c.122_143del p.Q41Pfs*112 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by pindel, varscan2
- FOXK2 | c.462C>A p.F154L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- IFNAR1 | c.1043T>A p.I348N | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- NFKBIL1 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2
- AL645922.1 | c.165G>C p.L55= | Silent (SNP) | VAF 98/228 reads (43%) | called by muse, mutect2, varscan2
- NOP9 | c.1428C>A p.A476= | Silent (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- PDE2A | c.1141C>T p.L381= | Silent (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- TICAM1 | c.336G>T p.S112= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- DSCR4 | n.202C>A | RNA (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
